Somatic mutation profile of tumor specimen HCM-CSHL-0811-C55-01A (aliquot HCM-CSHL-0811-C55-01A-11D-A85L-36) from HCMI case HCM-CSHL-0811-C55, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IB; FIGO stage: Stage IB; Tumor grade: G3.
Specimen HCM-CSHL-0811-C55-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53028788-8834-4fed-87bf-0a8592605d4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0811-C55-11A (Solid Tissue Normal), aliquot HCM-CSHL-0811-C55-11A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b8f9f3a-ea63-4f13-8032-083f862cb800

The open-access MAF lists 95 somatic variants for this specimen: 72 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 21, Nonsense Mutation 3, Frame Shift Del 2, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.5687A>C p.K1896T | Missense Mutation (SNP) | VAF 123/722 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781116621, COSV101240158; called by muse, mutect2, varscan2
- AK9 | c.1984G>C p.D662H | Missense Mutation (SNP) | VAF 104/504 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV58137224; called by muse, mutect2, varscan2
- CACNA1B | c.2827C>A p.P943T | Missense Mutation (SNP) | VAF 590/612 reads (96%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs986733832; called by muse, mutect2, varscan2
- CACNA1E | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 466/988 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs1458093500, COSV62398100, COSV62413841; called by muse, varscan2
- CFAP47 | c.2582G>A p.R861Q | Missense Mutation (SNP) | VAF 198/587 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs758566001, COSV52884941; called by muse, mutect2, varscan2
- CFAP70 | c.2656C>T p.H886Y | Missense Mutation (SNP) | VAF 126/468 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1184993071; called by muse, varscan2
- CILP2 | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 680/707 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs773513832, COSV52280855; called by muse, varscan2
- FAM13C | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 133/473 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.517); catalogued as rs756854158, COSV53245798, COSV53247716; called by muse, mutect2, varscan2
- GLRA2 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 327/968 reads (34%) | catalogued as COSV54342596; called by muse, mutect2, varscan2
- HCN1 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 287/867 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.083); catalogued as rs727503956; called by muse, mutect2, varscan2
- MAP4K1 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 486/3960 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs1421857461, COSV67712269; called by muse, varscan2
- MYCN | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 240/1251 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55257613; called by muse, mutect2, varscan2
- PC | c.1574C>T p.T525M | Missense Mutation (SNP) | VAF 433/693 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.342); catalogued as rs146840773; called by muse, mutect2, varscan2
- PCDH17 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 53/1399 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV64971777, COSV64972890; called by muse, mutect2
- PDGFRA | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 24/430 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs752886996, COSV57274391; ClinVar: uncertain significance; called by muse, mutect2
- PDS5A | c.3891G>C p.K1297N | Missense Mutation (SNP) | VAF 296/593 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV57831585; called by muse, mutect2, varscan2
- PTPRF | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 632/1188 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs752081368, COSV63442147; called by muse, varscan2
- SCN1A | c.2615C>G p.S872C (on ENST00000303395 / NM_001202435.3; = p.S861C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/366 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1311651; called by muse, mutect2, varscan2
- SERPINC1 | c.1288A>T p.N430Y | Missense Mutation (SNP) | VAF 439/973 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as CM113686; called by muse, mutect2, varscan2
- THBS2 | c.1568G>T p.S523I | Missense Mutation (SNP) | VAF 264/1119 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs772389872; called by muse, mutect2, varscan2
- TMEM219 | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 314/473 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV54243437; called by muse, mutect2, varscan2
- TMEM242 | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 256/1064 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV65654306; called by muse, mutect2, varscan2
- TMEM71 | c.419C>G p.S140C (on ENST00000523829 / NM_001382398.1; = p.S121C on NM_144649.3) | Missense Mutation (SNP) | VAF 455/950 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100785715; called by muse, mutect2, varscan2
- WASHC4 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV59890863; called by muse, mutect2, varscan2
- ZNF790 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 188/3070 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63212328; called by muse, mutect2
- ABCF2 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 295/846 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- AOC2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 273/1232 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ARID4B | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 127/565 reads (22%) | called by mutect2, varscan2
- ASNSD1 | c.1322G>C p.R441T | Missense Mutation (SNP) | VAF 188/1053 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BICDL1 | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 281/819 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- BMPR1B | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 92/194 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CCDC148 | c.1407G>C p.L469F | Missense Mutation (SNP) | VAF 180/659 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- CLIC2 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 266/834 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CNNM3 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 340/902 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CUBN | c.795C>G p.D265E | Missense Mutation (SNP) | VAF 393/1496 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DEDD | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 510/1076 reads (47%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DYNC1H1 | c.3204C>G p.I1068M | Missense Mutation (SNP) | VAF 326/546 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ECPAS | c.1420C>G p.L474V | Missense Mutation (SNP) | VAF 149/328 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- EIF6 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 187/1209 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ELOC | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 144/647 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXQ1 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 1070/1532 reads (70%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.007); called by muse, mutect2
- HIF1A | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IRF6 | c.362del p.G121Afs*46 | Frame Shift Del (DEL) | VAF 136/660 reads (21%) | called by mutect2, pindel, varscan2
- KIF11 | c.1886A>T p.K629M | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- LRP1B | c.3358A>T p.I1120F | Missense Mutation (SNP) | VAF 146/155 reads (94%) | SIFT tolerated (0.19); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- LRRC41 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 326/1283 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAPK11 | c.646C>A p.L216M | Missense Mutation (SNP) | VAF 470/496 reads (95%) | SIFT tolerated (1); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MPRIP | c.196_201del p.S66_R67del | In Frame Del (DEL) | VAF 305/332 reads (92%) | called by mutect2, pindel, varscan2
- NRDE2 | c.1017G>C p.M339I | Missense Mutation (SNP) | VAF 141/412 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- OR2G3 | c.395A>C p.Y132S | Missense Mutation (SNP) | VAF 494/963 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- OR5D14 | c.531C>A p.N177K | Missense Mutation (SNP) | VAF 203/740 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- PHF3 | c.3838G>A p.E1280K | Missense Mutation (SNP) | VAF 138/595 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNB3 | c.4412G>T p.G1471V | Missense Mutation (SNP) | VAF 310/926 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- POLR1H | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 698/1001 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPA1 | c.3497G>C p.R1166T | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RPS6KL1 | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 201/597 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- S100PBP | c.1149_1150del p.Y383* | Frame Shift Del (DEL) | VAF 114/694 reads (16%) | called by mutect2, pindel, varscan2
- SAT1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 239/735 reads (33%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SFRP2 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 560/575 reads (97%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLCO1C1 | c.1396T>G p.S466A | Missense Mutation (SNP) | VAF 127/517 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SLFN13 | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 473/990 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK3 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 204/850 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SPTB | c.3590C>T p.P1197L | Missense Mutation (SNP) | VAF 123/1096 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- SRSF10 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 256/894 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- STXBP5 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 307/451 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SZT2 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 170/770 reads (22%) | called by muse, mutect2, varscan2
- TDRD12 | c.2959G>A p.E987K (on ENST00000444215; = p.E992K on NM_001366102.1) | Missense Mutation (SNP) | VAF 257/4940 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2
- TIGD6 | c.405G>C p.L135F | Missense Mutation (SNP) | VAF 231/801 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TRAV8-1 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 446/665 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- VSIG10 | c.373C>G p.Q125E | Missense Mutation (SNP) | VAF 202/713 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF181 | c.1186C>G p.Q396E | Missense Mutation (SNP) | VAF 168/6988 reads (2%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- ZNF598 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 274/594 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- AKT2 | c.1089C>T p.L363= | Silent (SNP) | VAF 271/1223 reads (22%) | catalogued as rs1424888494; called by muse, mutect2, varscan2
- ALOX5 | c.354G>A p.K118= | Silent (SNP) | VAF 235/754 reads (31%) | called by muse, mutect2, varscan2
- ATRX | c.6663A>G p.E2221= | Silent (SNP) | VAF 125/517 reads (24%) | called by muse, mutect2, varscan2
- CCDC127 | c.498C>A p.L166= | Silent (SNP) | VAF 419/664 reads (63%) | catalogued as COSV99722912; called by muse, varscan2
- CCDC137 | c.144G>A p.K48= | Silent (SNP) | VAF 375/386 reads (97%) | catalogued as rs766673567; called by muse, mutect2, varscan2
- CEBPA | c.939G>A p.K313= | Silent (SNP) | VAF 552/6976 reads (8%) | catalogued as COSV57195681; called by muse, mutect2
- CEP162 | c.3567G>A p.E1189= | Silent (SNP) | VAF 117/503 reads (23%) | catalogued as rs1415482702; called by muse, mutect2, varscan2
- DENND1A | c.960C>T p.F320= | Silent (SNP) | VAF 178/374 reads (48%) | catalogued as rs373730181; called by muse, mutect2, varscan2
- E2F2 | c.681C>T p.L227= | Silent (SNP) | VAF 290/1169 reads (25%) | called by muse, mutect2, varscan2
- FSIP2 | c.3102T>C p.H1034= | Silent (SNP) | VAF 77/300 reads (26%) | called by muse, mutect2, varscan2
- GPR158 | c.711C>T p.R237= | Silent (SNP) | VAF 634/2222 reads (29%) | called by muse, varscan2
- GUCY2F | c.2100C>T p.L700= | Silent (SNP) | VAF 195/582 reads (34%) | called by muse, mutect2, varscan2
- IL1R1 | c.1704C>T p.L568= | Silent (SNP) | VAF 272/418 reads (65%) | catalogued as rs200300972, COSV52105713; called by muse, mutect2, varscan2
- IMPG2 | c.2424C>G p.L808= | Silent (SNP) | VAF 453/1022 reads (44%) | catalogued as COSV51985620; called by muse, mutect2, varscan2
- MMRN2 | c.1824G>A p.A608= | Silent (SNP) | VAF 380/1232 reads (31%) | catalogued as rs1259086393; called by muse, mutect2, varscan2
- PRDM4 | c.2136G>A p.L712= | Silent (SNP) | VAF 311/532 reads (58%) | called by muse, mutect2, varscan2
- RPUSD3 | c.570G>T p.L190= | Silent (SNP) | VAF 211/837 reads (25%) | called by muse, mutect2, varscan2
- RYR2 | c.702C>T p.L234= | Silent (SNP) | VAF 213/906 reads (24%) | called by muse, mutect2, varscan2
- TFR2 | c.1077C>T p.I359= | Silent (SNP) | VAF 269/818 reads (33%) | catalogued as COSV56154989; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1632C>G p.V544= | Silent (SNP) | VAF 192/797 reads (24%) | called by muse, mutect2, varscan2
- ZC3HAV1L | c.681G>C p.L227= | Silent (SNP) | VAF 165/624 reads (26%) | called by muse, mutect2, varscan2
- MGAM | c.4618+3219G>T | Intron (SNP) | VAF 392/633 reads (62%) | catalogued as COSV72076310; called by muse, mutect2, varscan2
- MXRA7 | c.343-246G>A | Intron (SNP) | VAF 282/1144 reads (25%) | catalogued as rs780717923, COSV63321750; called by muse, mutect2
